BEATAML1.0 case 2078 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/f2f313bb-9743-4e11-93f6-97091aba1622

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Primary myelofibrosis: ICD-O-3 morphology code: 9961/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,437 days); Progression or recurrence: no; ELN risk classification: Adverse.

Biospecimens (3 samples)
- Samples BA2319D, BA2838D (2 with the same recorded description): Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample BA2346D: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
